Somatic mutation profile of tumor specimen TCGA-DM-A0X9-01A (aliquot TCGA-DM-A0X9-01A-11D-A152-10) from TCGA case TCGA-DM-A0X9, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.8 years (26,217 days).
Specimen TCGA-DM-A0X9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b4aaebf-f6a1-477d-b889-bba75b4a4800.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A0X9-10A (Blood Derived Normal), aliquot TCGA-DM-A0X9-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ef96c7f-c3ee-42a2-9706-f3f8ef252de2

The open-access MAF lists 196 somatic variants for this specimen: 153 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 39, Nonsense Mutation 13, Frame Shift Del 3, Splice Site 2, Intron 2, Splice Region 2, Frame Shift Ins 1, 5'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 50/149 reads (34%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 49/114 reads (43%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 147/258 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 97/316 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 39/355 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV55875690, COSV55899999; called by muse, mutect2, varscan2
- A2ML1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV55292263; called by muse, mutect2, varscan2
- ABCA1 | c.3281C>T p.A1094V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211257538, COSV101036542; called by muse, mutect2, varscan2
- AC100868.1 | c.1427C>A p.A476D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV51844596, COSV99226405; called by muse, mutect2, varscan2
- AGFG1 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 161/433 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV59512739; called by mutect2, varscan2
- AHDC1 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99899420; called by muse, mutect2
- AHNAK2 | c.13702G>A p.V4568I | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.199); catalogued as rs569250855, COSV60908182; called by muse, mutect2, varscan2
- AKAP6 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV55213659, COSV99801568; called by muse, mutect2
- APOB | c.7913A>C p.N2638T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV99266073; called by muse, mutect2, varscan2
- ARFGEF1 | c.2554T>C p.Y852H | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51610462; called by muse, mutect2, varscan2
- ARHGAP32 | c.3301G>A p.D1101N (on ENST00000310343 / NM_001378025.1; = p.D752N on NM_014715.4) | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs746571955, COSV59849824; called by muse, mutect2, varscan2
- ARSI | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.375); catalogued as rs775966190, COSV60817266; called by muse, mutect2, varscan2
- BACH2 | c.2267C>G p.A756G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as COSV57589488, COSV57596047; called by muse, mutect2, varscan2
- BCL9 | c.660+1G>T p.X220_splice | Splice Site (SNP) | VAF 33/49 reads (67%) | catalogued as COSV52344080, COSV52345864; called by muse, mutect2, varscan2
- BRD2 | c.1999C>T p.H667Y | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV66373651; called by muse, mutect2, varscan2
- BRD3 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs1440535498, COSV100324749, COSV57701536; called by muse, varscan2
- BRINP1 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs765012305, COSV56291938; called by muse, mutect2, varscan2
- CACNA1A | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV64200556; called by muse, mutect2, varscan2
- CD19 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100218159; called by muse, mutect2, varscan2
- CDH2 | c.97A>T p.K33* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV52283477; called by muse, mutect2, varscan2
- CDHR5 | c.1959G>T p.E653D (on ENST00000358353 / NM_001171968.2; = p.E659D on NM_021924.5) | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.534); catalogued as COSV57643864; called by muse, mutect2, varscan2
- CFHR2 | c.274G>C p.V92L | Missense Mutation (SNP) | VAF 37/404 reads (9%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.984); catalogued as COSV66381353; called by muse, mutect2
- CHMP1A | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs764268997, COSV53683492; called by muse, mutect2, varscan2
- CLDN10 | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV54824702; called by muse, mutect2, varscan2
- CNOT1 | c.6467G>A p.S2156N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV55318102; called by muse, mutect2, varscan2
- COL4A5 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs752399898, COSV60363822; called by muse, mutect2, varscan2
- CPAMD8 | c.4778C>T p.A1593V (on ENST00000651564; = p.A1546V on NM_015692.5) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV71596747; called by muse, mutect2, varscan2
- CSMD3 | c.6692G>A p.R2231Q (on ENST00000297405 / NM_001363185.1; = p.R2127Q on NM_052900.3) | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.6); catalogued as rs751658267, COSV52145865, COSV99832218; called by muse, mutect2, varscan2
- CSNK2A1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777370152, COSV53933669; called by muse, mutect2, varscan2
- CTCF | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs771567232, COSV50467549; called by muse, mutect2, varscan2
- CTNNA2 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV58157507; called by muse, mutect2, varscan2
- CTNNBL1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs1201435886, COSV63744713; called by muse, mutect2, varscan2
- CTTNBP2 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs772211877, COSV50406121; called by muse, mutect2, varscan2
- CXCR3 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.793); catalogued as rs1240827614, COSV65462384; called by muse, varscan2
- DAAM2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs752703893, COSV51337433; called by muse, mutect2, varscan2
- DAZAP1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV51833752, COSV51834764; called by muse, mutect2, varscan2
- DCAF8L1 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71595349; called by muse, mutect2, varscan2
- DECR2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs756055283, COSV54794957; called by muse, mutect2, varscan2
- DNAH9 | c.5353C>A p.H1785N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52355037; called by muse, mutect2, varscan2
- DSC2 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs374613780; called by muse, mutect2, varscan2
- DSP | c.5959G>T p.D1987Y | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV65793361; called by muse, mutect2, varscan2
- EPHA3 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV60710490, COSV60714210; called by muse, mutect2, varscan2
- EPHB1 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.797); catalogued as rs536029159, COSV67659446; called by muse, mutect2, varscan2
- ESX1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.347); catalogued as rs1556395640, COSV65423900; called by muse, mutect2, varscan2
- ETS1 | c.774C>G p.Y258* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as COSV60094199; called by muse, mutect2, varscan2
- EXOC4 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs978166030, COSV54102288; called by muse, mutect2, varscan2
- EYA2 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV57945199; called by muse, mutect2, varscan2
- FAM47C | c.3004G>T p.A1002S | Missense Mutation (SNP) | VAF 94/327 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV63727349; called by muse, mutect2, varscan2
- FAT4 | c.5380G>T p.G1794* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV100628924; called by muse, mutect2, varscan2
- FBP2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766630515, COSV64694861; called by muse, mutect2, varscan2
- FIGNL1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV63553630; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1551T>G p.H517Q | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV58556866; called by muse, mutect2, varscan2
- FRY | c.3791T>A p.F1264Y | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66572047; called by muse, mutect2, varscan2
- GLUD2 | c.1062A>T p.Q354H | Missense Mutation (SNP) | VAF 209/357 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV60152127; called by muse, mutect2, varscan2
- GPATCH1 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as rs773666485, COSV50117107; called by muse, mutect2, varscan2
- H1-2 | c.446_448del p.K149del | In Frame Del (DEL) | VAF 48/162 reads (30%) | catalogued as rs779842031; called by pindel, varscan2
- HBS1L | c.1910A>G p.K637R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs1374642673, COSV63201603; called by muse, mutect2, varscan2
- HTR5A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs780790670, COSV55282302, COSV55284114; called by muse, mutect2, varscan2
- IL17RD | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756741660, COSV56339002; called by muse, mutect2, varscan2
- INA | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 84/202 reads (42%) | catalogued as COSV63975632, COSV63976475; called by muse, mutect2, varscan2
- INF2 | c.2880C>T p.V960= | Splice Region (SNP) | VAF 40/92 reads (43%) | catalogued as COSV53033334; called by muse, mutect2, varscan2
- INHBB | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1001095566, COSV54677954; called by muse, mutect2, varscan2
- IRAK4 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV71210548; called by muse, mutect2, varscan2
- ITGAL | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs749508499, COSV63319940; called by muse, mutect2, varscan2
- ITIH6 | c.737T>A p.F246Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV54490249; called by muse, mutect2, varscan2
- KCNK2 | c.803G>T p.G268V (on ENST00000444842 / NM_001017425.3; = p.G253V on NM_014217.4) | Missense Mutation (SNP) | VAF 66/341 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222196; called by muse, mutect2, varscan2
- KDM6B | c.4858G>T p.E1620* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV54682760; called by muse, mutect2
- KRTAP24-1 | c.686G>T p.R229I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100447323, COSV61089636; called by muse, mutect2, varscan2
- LAMA3 | c.7326A>C p.K2442N (on ENST00000313654 / NM_198129.4; = p.K833N on NM_000227.6) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99335052; called by muse, mutect2
- LAMA5 | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs142481643; called by muse, mutect2, varscan2
- MAN1C1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755018052, COSV56045358; called by muse, mutect2, varscan2
- MAPK8IP3 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV50188983; called by muse, mutect2
- MAST2 | c.2785C>T p.R929C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs1389345208, COSV63618992; called by muse, mutect2, varscan2
- MEAF6 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV56162605, COSV56163847; called by muse, mutect2, varscan2
- MEGF8 | c.4517G>A p.R1506H (on ENST00000251268 / NM_001271938.2; = p.R1439H on NM_001410.3) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as rs749669318, COSV52080736; called by muse, mutect2, varscan2
- MEIS1 | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99715344; called by muse, mutect2, varscan2
- MITF | c.730A>T p.M244L (on ENST00000448226 / NM_006722.3; = p.M138L on NM_000248.4) | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV58832412, COSV58836846; called by muse, mutect2, varscan2
- MUC2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.15); catalogued as rs757797699; called by muse, mutect2, varscan2
- MYOD1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51453913; called by muse, mutect2, varscan2
- NAV2 | c.3679G>A p.G1227R (on ENST00000396087 / NM_001244963.2; = p.G1204R on NM_145117.5) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs895534359, COSV60660428; called by muse, mutect2, varscan2
- NCKAP1L | c.3364C>T p.R1122W | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs150918174; called by muse, mutect2, varscan2
- NFATC2 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 86/115 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1272354225, COSV65357238; called by muse, mutect2, varscan2
- NOS2 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780524247, COSV58224586; called by muse, mutect2, varscan2
- NYAP2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs777377168, COSV56007845; called by muse, mutect2, varscan2
- OR10H1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs780602555, COSV58471996; called by muse, mutect2, varscan2
- OR2AG2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.103); catalogued as COSV58455411; called by muse, mutect2
- OR2T27 | c.12C>A p.S4R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV61282460; called by muse, mutect2, varscan2
- OR4A16 | c.876del p.M292Ifs*5 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as COSV59041753, COSV59043563; called by mutect2, pindel, varscan2
- OR5B3 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58677716, COSV58678322; called by muse, mutect2, varscan2
- OR5L1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61734246; called by muse, mutect2, varscan2
- OR5L2 | c.878G>T p.R293I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV65724291; called by muse, mutect2, varscan2
- OR6K2 | c.778T>A p.Y260N | Missense Mutation (SNP) | VAF 115/200 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62743611; called by muse, mutect2, varscan2
- OR7E24 | c.1010A>C p.Y337S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV71702242; called by muse, mutect2, varscan2
- OR9I1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs769620522, COSV56926317; called by muse, mutect2, varscan2
- OTUD6A | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs754807874, COSV57972961; called by muse, mutect2, varscan2
- PAPPA | c.1548C>G p.F516L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV100072759, COSV60283763, COSV60285609; called by muse, mutect2, varscan2
- PAPPA2 | c.2466A>C p.Q822H | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62779945; called by muse, mutect2, varscan2
- PCLO | c.15343G>T p.A5115S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV61641487; called by muse, mutect2, varscan2
- PCNX2 | c.4933G>A p.A1645T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs769718791, COSV50812373; called by muse, mutect2, varscan2
- PCSK6 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as rs373433666; called by muse, mutect2, varscan2
- PKNOX2 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs781020037, COSV53541095; called by mutect2, varscan2
- PLEKHH3 | c.124T>C p.F42L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.935); catalogued as COSV53189734; called by muse, mutect2, varscan2
- PRR30 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as rs765597175, COSV53206570, COSV99574537; called by muse, mutect2, varscan2
- RAB40AL | c.161C>G p.T54S | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV54434743; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, mutect2, varscan2
- RASGRP3 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 93/222 reads (42%) | catalogued as COSV67822626; called by muse, mutect2, varscan2
- RGL3 | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV66509376; called by muse, mutect2, varscan2
- RIMS1 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768258718, COSV99327609; called by muse, mutect2, varscan2
- RNF113A | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV101007065; called by muse, mutect2, varscan2
- RNF128 | c.781C>T p.R261C (on ENST00000255499 / NM_194463.2; = p.R235C on NM_024539.3) | Missense Mutation (SNP) | VAF 221/999 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs750124343, COSV55251869; called by muse, mutect2, varscan2
- RSBN1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.866); catalogued as COSV54733016; called by muse, mutect2, varscan2
- RYR1 | c.3994G>A p.E1332K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs896157692, COSV62100300; called by muse, mutect2, varscan2
- RYR1 | c.7021G>A p.V2341I | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as rs767615522, COSV62089431; called by muse, mutect2, varscan2
- SCAF4 | c.600G>A p.Q200= | Splice Region (SNP) | VAF 58/124 reads (47%) | catalogued as COSV54584953; called by muse, mutect2, varscan2
- SCN8A | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as rs866054004, COSV61983895; called by muse, mutect2, varscan2
- SCN8A | c.3664A>G p.I1222V | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV61983900; called by muse, mutect2, varscan2
- SLITRK4 | c.1141A>G p.K381E | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV62024546; called by muse, mutect2, varscan2
- SPIN3 | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 96/177 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as COSV66529273; called by muse, mutect2, varscan2
- STRIP2 | c.626T>A p.M209K | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV50805158; called by muse, mutect2, varscan2
- SUOX | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV56269294; called by muse, mutect2, varscan2
- SUPT6H | c.1299C>A p.D433E | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.135); catalogued as COSV100112498; called by muse, mutect2, varscan2
- TAS2R1 | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV101225786; called by muse, mutect2, varscan2
- TBC1D3B | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1193421897; called by mutect2, varscan2
- TCF20 | c.4021A>G p.I1341V | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.891); catalogued as COSV59492762; called by muse, mutect2, varscan2
- TCP11L1 | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV57515741; called by muse, mutect2, varscan2
- TEX13B | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs776336502, COSV57202656; called by muse, mutect2, varscan2
- TMEM26 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV67492869; called by muse, mutect2, varscan2
- TMPRSS11D | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as rs1265564936, COSV52223958; called by muse, mutect2, varscan2
- TMPRSS15 | c.1823C>A p.T608N | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99518200; called by muse, mutect2, varscan2
- TPO | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs753786141, COSV61103439; called by muse, mutect2, varscan2
- TREX2 | c.-1004-1G>A | Splice Site (SNP) | VAF 20/70 reads (29%) | catalogued as COSV57849598; called by muse, mutect2, varscan2
- TTC27 | c.1794G>A p.W598* | Nonsense Mutation (SNP) | VAF 88/264 reads (33%) | catalogued as COSV58653274; called by muse, mutect2, varscan2
- TTLL7 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 120/285 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774042881, COSV53081370, COSV53085301; called by muse, mutect2, varscan2
- TXLNB | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as COSV64444380, COSV64445285; called by muse, mutect2, varscan2
- VCAN | c.5765G>T p.R1922M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV54107568; called by muse, mutect2, varscan2
- ZBTB46 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs767094923, COSV55511105; called by muse, mutect2, varscan2
- ZFHX4 | c.2260G>A p.G754R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs771826272, COSV50482685, COSV99257354; called by muse, mutect2, varscan2
- ZFHX4 | c.9938G>T p.G3313V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV51437406; called by muse, mutect2, varscan2
- ZFP82 | c.680A>T p.E227V | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as rs780307893, COSV67565601; called by muse, mutect2, varscan2
- ZNF329 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 272/407 reads (67%) | catalogued as rs143513293, COSV100798804; called by muse, mutect2, varscan2
- ZNF385D | c.574T>A p.S192T | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99875027; called by muse, mutect2, varscan2
- ZNF536 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs763225279, COSV62826124; called by muse, mutect2, varscan2
- ZNF543 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV58627086; called by muse, mutect2, varscan2
- ZNF610 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 24/128 reads (19%) | catalogued as COSV58345193; called by muse, mutect2, varscan2
- ZNF98 | c.996C>A p.S332R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1220393520; called by muse, varscan2
- CLSPN | c.290dup p.N97Kfs*15 | Frame Shift Ins (INS) | VAF 62/166 reads (37%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- INPP4A | c.257_260del p.T86Rfs*12 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- VCAN | c.1191del p.V398Wfs*22 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel, varscan2
- ABCD2 | c.327G>T p.L109= | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as COSV58052275; called by muse, mutect2, varscan2
- ACAT1 | c.166T>C p.L56= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV54921214; called by muse, mutect2, varscan2
- ACSL4 | c.2135A>G p.*712= (on ENST00000340800 / NM_022977.2; = p.*671= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/254 reads (28%) | catalogued as COSV61614813; called by muse, mutect2, varscan2
- ALPL | c.393C>T p.S131= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV66380021; called by muse, mutect2, varscan2
- ATP2A3 | c.520C>A p.R174= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV59230271; called by muse, mutect2, varscan2
- ATP2A3 | c.519G>A p.L173= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV59230289; called by muse, mutect2, varscan2
- ATP9A | c.114C>T p.P38= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV58767857; called by muse, mutect2, varscan2
- CCDC185 | c.1437G>A p.Q479= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs993361210, COSV64821099; called by muse, mutect2, varscan2
- CD40LG | c.390C>T p.A130= | Silent (SNP) | VAF 128/254 reads (50%) | catalogued as COSV65698645; called by muse, mutect2, varscan2
- CFHR1 | c.408C>T p.T136= | Silent (SNP) | VAF 73/126 reads (58%) | catalogued as COSV57627593; called by muse, mutect2, varscan2
- DDX1 | c.1962C>T p.N654= | Silent (SNP) | VAF 80/194 reads (41%) | catalogued as rs371305987; called by muse, mutect2, varscan2
- DPY30 | c.6G>A p.E2= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs1396436281, COSV54459092; called by muse, mutect2, varscan2
- ERH | c.270G>A p.K90= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as COSV53680877, COSV99384029; called by muse, mutect2, varscan2
- FANCL | c.1014A>G p.L338= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as rs1021979267, COSV52075154; called by muse, mutect2, varscan2
- FSHR | c.1890C>G p.T630= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as COSV58625754; called by muse, mutect2, varscan2
- GRIN2B | c.3159C>T p.D1053= | Silent (SNP) | VAF 59/218 reads (27%) | catalogued as rs776986575, COSV74205137, COSV74206667; called by muse, mutect2, varscan2
- HMX3 | c.114C>T p.N38= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV63501794; called by muse, mutect2, varscan2
- LAMA5 | c.9498G>A p.A3166= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as rs776827129, COSV53362189; called by muse, mutect2, varscan2
- MAPK10 | c.594G>A p.L198= (on ENST00000359221 / NM_001351625.2; = p.L236= on NM_002753.5) | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs1267536247, COSV60384789; called by muse, mutect2, varscan2
- NHLRC2 | c.1206C>T p.A402= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV65175092; called by muse, mutect2, varscan2
- NRAP | c.2781G>A p.R927= (on ENST00000359988 / NM_001322945.2; = p.R892= on NM_006175.4) | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs753450735, COSV63491452; called by muse, mutect2, varscan2
- OTOL1 | c.96G>A p.T32= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs376103439; called by muse, mutect2, varscan2
- PCDHB8 | c.2025G>A p.P675= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV50777474; called by muse, mutect2, varscan2
- PDZD2 | c.2895C>T p.Y965= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs371895164; called by muse, mutect2, varscan2
- PKD1L1 | c.6063G>A p.P2021= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs924338918, COSV56967982; called by muse, mutect2, varscan2
- POU3F3 | c.1017G>A p.T339= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as COSV63721913; called by muse, mutect2, varscan2
- PSD | c.1776G>A p.G592= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as COSV50047180; called by muse, mutect2, varscan2
- RFTN2 | c.738T>C p.Y246= | Silent (SNP) | VAF 57/149 reads (38%) | catalogued as COSV99695673; called by muse, mutect2, varscan2
- RFX4 | c.823T>C p.L275= (on ENST00000392842 / NM_213594.3; = p.L181= on NM_032491.6) | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV57576853; called by muse, mutect2, varscan2
- SCN8A | c.1752G>A p.A584= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as rs775442359, COSV61983887; called by muse, mutect2, varscan2
- SLC18A2 | c.513C>T p.V171= | Silent (SNP) | VAF 128/366 reads (35%) | catalogued as COSV53691189; called by muse, mutect2, varscan2
- SMARCA4 | c.3348T>C p.F1116= | Silent (SNP) | VAF 60/121 reads (50%) | catalogued as rs1182379000, COSV100758642; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBC1D9 | c.183T>C p.A61= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV65932368; called by muse, mutect2, varscan2
- TET1 | c.3819C>T p.N1273= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs755989600, COSV65382662; called by muse, mutect2, varscan2
- TMX4 | c.813C>T p.G271= | Silent (SNP) | VAF 82/469 reads (17%) | catalogued as rs369576638; called by muse, mutect2, varscan2
- TOGARAM2 | c.2022C>T p.G674= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as COSV101091194; called by muse, mutect2, varscan2
- TUBB2B | c.1308C>T p.F436= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs746506962, COSV52533239; called by muse, mutect2, varscan2
- UNC13C | c.6447C>T p.I2149= | Silent (SNP) | VAF 68/147 reads (46%) | catalogued as rs369992580; called by muse, mutect2, varscan2
- ZNF419 | c.846T>A p.T282= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV55660596; called by muse, mutect2, varscan2
- DOCK8 | chr9:214646 G>A | 5'Flank (SNP) | VAF 8/16 reads (50%) | catalogued as rs931848173, COSV101213675; called by muse, varscan2
- OBSCN | c.11660-2603C>T | Intron (SNP) | VAF 64/120 reads (53%) | catalogued as rs753584750, COSV52735756; called by muse, mutect2, varscan2
- SH3KBP1 | c.521-3597G>A | Intron (SNP) | VAF 118/234 reads (50%) | catalogued as rs1035012237, COSV101114412; called by muse, mutect2, varscan2
- TLX2 | c.-1G>A | 5'UTR (SNP) | VAF 34/82 reads (41%) | catalogued as COSV99283679; called by muse, mutect2, varscan2
